Gene-level copy-number profile of tumor specimen TCGA-2G-AAI5-01A from TCGA case TCGA-2G-AAI5, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 37.0 years (13,503 days).
Specimen TCGA-2G-AAI5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ff9e82ec-93ec-4f55-abbe-4997f8addb3b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAI5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/9ce36846-ce6d-4cfc-a0ad-391ae6a6ca50

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,274; copy number 2: 11,268; copy number 3: 25,710; copy number 4: 18,761; copy number 5: 520; copy number 6: 1,062; copy number 7: 52; copy number 11: 253; copy number 15: 9.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 314 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:20,338,805–24,628,987, 313 genes, copy number 7–15 (within-gene range 3–15) (broad region; genes not listed).
- chr22:24,598,054–24,599,398, 1 gene, copy number 15 (within-gene range 3–15): AP000356.1.

Autosomal genes at a single copy (total copy number 1): 762. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
